Surgical pathology report (de-identified scan), TCGA case TCGA-28-2512, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2512-01A (Primary Tumor).

CGA-28-2512

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

Reason for Addendum #2: Additional studies/stains/opinion(s)

DIAGNOSIS:

- A. BRAIN, RIGHT TEMPORAL, BIOPSY:
- Giant cell glioblastoma, WHO grade IV
- B. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI#1:
- Giant cell glioblastoma, WHO grade IV
- Tumor cellularity is 95%
- Tumor necrosis is 3%
- C. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI#2:
- Giant cell glioblastoma, WHO grade IV
- Tumor cellularity is 95%
- Tumor necrosis is 1%
- D. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI#3:
- Giant cell glioblastoma, WHO grade IV
- Tumor cellularity is 95%
- Tumor necrosis is 10%
- E. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI#4:
- Giant cell glioblastoma, WHO grade IV
- Tumor cellularity is 95%
- Tumor necrosis is 1%
- F. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI#5:
- Giant cell glioblastoma, WHO grade IV
- Tumor cellularity is 95%
- Tumor necrosis is 0%
- G. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:
- Giant cell glioblastoma, WHO grade IV

IDC2a: Selected slides were reviewed in consultation with Dr. [REDACTED]

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar [REDACTED]. Hence, the 95% result in this case suggests the possibility of a relatively diminished response to Temodar.

Source: NCI Genomic Data Commons file d097b9bd-7317-4c7d-a936-f51f29c6d362 (TCGA-28-2512.1D7636D1-6604-4261-A368-5252A7F30FA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).